CCDI case PBBRDV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/55a0f1be-99ac-4631-b1aa-09ed5a8097b9

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.9 years (4,332 days).

Biospecimens (3 samples)
- Sample 0DEQWX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEQX1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEQXQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
